Somatic mutation profile of tumor specimen 0DIW84 from CCDI case PBBWCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Intestinal tract, NOS; Age at diagnosis: 22.7 years (8,305 days).
Specimen 0DIW84: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12b42bec-d8b9-4763-ac77-d5a8ec799e39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW67 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80ad5e3f-facf-4431-8557-05df3a57bd8d

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 12 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Intron 7, 3'UTR 5, Nonsense Mutation 3, 5'UTR 3, Frame Shift Del 2, RNA 2, Splice Region 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO9 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 349/492 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV60382464; called by muse, mutect2, varscan2
- BAZ2B | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 152/394 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.243); catalogued as COSV58610990; called by muse, mutect2, varscan2
- CNTN5 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 223/968 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV54306589; called by muse, mutect2
- CYP2B6 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 188/476 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764288403, COSV100137551, COSV57843577; called by muse, varscan2
- F7 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 226/554 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs774908633, COSV60647010; called by muse, mutect2, varscan2
- FAM135B | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 221/575 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52709117, COSV52732702; called by muse, mutect2, varscan2
- FAM3A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 222/518 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782018344; called by muse, varscan2
- GRK7 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 326/808 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs36004830; called by muse, mutect2, varscan2
- HGS | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 331/839 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1246808058; called by muse, mutect2, varscan2
- HSPA6 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 239/660 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1407290183; called by muse, mutect2, varscan2
- IFNA4 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 182/278 reads (65%) | catalogued as COSV70180385; called by muse, varscan2
- MAB21L2 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 98/123 reads (80%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV58261608; called by muse, mutect2, varscan2
- MAGEL2 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 174/435 reads (40%) | SIFT tolerated, low confidence (0.11); catalogued as rs1372142044, COSV58566451; called by muse, mutect2, varscan2
- MAP2K1 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 192/488 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1567026612, COSV61068800; called by muse, mutect2, varscan2
- MEF2B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 173/413 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756052438, COSV50766301; called by mutect2, varscan2
- OBSCN | c.8983C>T p.R2995W | Missense Mutation (SNP) | VAF 160/422 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs376064743; called by muse, mutect2, varscan2
- OR4K2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1183463266; called by muse, mutect2, varscan2
- P2RX7 | c.294+1G>A p.X98_splice | Splice Site (SNP) | VAF 206/476 reads (43%) | catalogued as rs1453727947; called by muse, mutect2, varscan2
- PCDH8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 195/450 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58812355; called by muse, mutect2, varscan2
- PCDH8 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 187/526 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs752517249, COSV58815497; called by muse, mutect2, varscan2
- SLC5A11 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 213/262 reads (81%) | catalogued as rs997867392, COSV61740905; called by muse, mutect2, varscan2
- SYNE1 | c.20143G>A p.V6715M (on ENST00000367255 / NM_182961.4; = p.V6644M on NM_033071.3) | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145185413; ClinVar: uncertain significance; called by muse, mutect2
- TMEM160 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.157); catalogued as rs755036289; called by muse, mutect2, varscan2
- UNC13C | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 190/486 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as COSV99523823; called by muse, mutect2, varscan2
- APC | c.4497_4498del p.S1501Lfs*12 | Frame Shift Del (DEL) | VAF 259/389 reads (67%) | called by mutect2, pindel, varscan2
- ARR3 | c.787T>G p.S263A | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C14orf39 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 127/176 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1I | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 234/845 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK4 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 166/443 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CEP85L | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMPK2 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 179/447 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND5B | c.958T>C p.F320L | Missense Mutation (SNP) | VAF 24/554 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- EHBP1 | c.2334dup p.H779Tfs*10 | Frame Shift Ins (INS) | VAF 227/636 reads (36%) | called by mutect2, pindel, varscan2
- FAM47C | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 396/1062 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- HAS3 | c.1226T>A p.I409N | Missense Mutation (SNP) | VAF 165/221 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- HS3ST3A1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 191/260 reads (73%) | called by muse, mutect2, varscan2
- JARID2 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 212/504 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMTK2 | c.3486A>T p.E1162D | Missense Mutation (SNP) | VAF 192/430 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC19 | c.1108A>C p.N370H | Missense Mutation (SNP) | VAF 175/239 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LRRC71 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 258/710 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NR0B1 | c.1277T>C p.F426S | Missense Mutation (SNP) | VAF 194/537 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NUP133 | c.3117A>T p.E1039D | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR2B6 | c.161A>C p.K54T | Missense Mutation (SNP) | VAF 261/627 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- OR4Q2 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 236/309 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHC1 | c.1107C>T p.A369= | Splice Region (SNP) | VAF 120/277 reads (43%) | called by muse, mutect2, varscan2
- PKP2 | c.1933A>T p.I645F | Missense Mutation (SNP) | VAF 306/771 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PRSS35 | c.329A>T p.N110I | Missense Mutation (SNP) | VAF 297/780 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PTCHD3 | c.2162A>G p.N721S | Missense Mutation (SNP) | VAF 170/250 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SACS | c.13214C>T p.A4405V | Missense Mutation (SNP) | VAF 287/731 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCRN1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 239/566 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SETBP1 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 215/568 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC38A4 | c.567A>T p.E189D | Missense Mutation (SNP) | VAF 227/552 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SMC1B | c.2173_2182del p.K725Lfs*15 | Frame Shift Del (DEL) | VAF 96/538 reads (18%) | called by mutect2, pindel, varscan2
- SORCS1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 280/365 reads (77%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCE1 | c.197-7G>A | Splice Region (SNP) | VAF 27/324 reads (8%) | called by muse, mutect2
- THSD7B | c.3688C>A p.H1230N (on ENST00000272643; = p.H1228N on NM_001316349.2) | Missense Mutation (SNP) | VAF 204/481 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOPAZ1 | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 182/263 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM1 | c.3596T>A p.I1199N | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- TSPAN6 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 194/445 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- DNPH1 | c.162C>T p.T54= | Silent (SNP) | VAF 251/586 reads (43%) | catalogued as rs757817285; called by muse, mutect2, varscan2
- FCGBP | c.10920A>G p.L3640= | Silent (SNP) | VAF 159/367 reads (43%) | called by muse, mutect2, varscan2
- GK | c.903T>C p.F301= (on ENST00000427190 / NM_001205019.2; = p.F295= on NM_000167.6) | Silent (SNP) | VAF 109/282 reads (39%) | called by muse, mutect2, varscan2
- HMCN1 | c.4752C>T p.D1584= | Silent (SNP) | VAF 241/537 reads (45%) | catalogued as rs144362862; called by muse, mutect2, varscan2
- IFNA4 | c.450C>T p.I150= | Silent (SNP) | VAF 266/382 reads (70%) | catalogued as rs1164711865; called by muse, varscan2
- JUP | c.312C>T p.T104= | Silent (SNP) | VAF 203/481 reads (42%) | called by muse, mutect2, varscan2
- KRTAP24-1 | c.15C>A p.S5= | Silent (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- SDK1 | c.5181G>A p.P1727= | Silent (SNP) | VAF 192/533 reads (36%) | catalogued as rs375424679; called by muse, varscan2
- SHOX2 | c.381G>A p.A127= (on ENST00000441443 / NM_006884.3; = p.A151= on NM_003030.4) | Silent (SNP) | VAF 18/610 reads (3%) | catalogued as COSV67463884; called by muse, mutect2
- TCHP | c.963C>T p.V321= | Silent (SNP) | VAF 19/706 reads (3%) | catalogued as rs1301472189; called by muse, mutect2
- VIRMA | c.2463T>C p.N821= | Silent (SNP) | VAF 137/390 reads (35%) | called by muse, mutect2, varscan2
- ZNF570 | c.1551G>A p.Q517= | Silent (SNP) | VAF 131/371 reads (35%) | catalogued as COSV57578056; called by muse, mutect2, varscan2
- AC012060.1 | n.1117G>A | RNA (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- AL731532.1 | n.1807C>A | RNA (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- ATP5PO | c.441+84A>C | Intron (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- CDH18 | c.*40G>T | 3'UTR (SNP) | VAF 169/863 reads (20%) | called by muse, mutect2, varscan2
- CLEC4C | c.*71A>G | 3'UTR (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- COPB2 | c.2303+14A>G | Intron (SNP) | VAF 147/403 reads (36%) | called by muse, mutect2, varscan2
- COPS7A | c.*47C>T | 3'UTR (SNP) | VAF 129/259 reads (50%) | catalogued as rs775571700; called by muse, mutect2, varscan2
- EPHA6 | c.1114+22114T>C | Intron (SNP) | VAF 167/476 reads (35%) | called by muse, mutect2, varscan2
- GLYR1 | c.-1G>C | 5'UTR (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- LDB3 | c.690-4826G>A | Intron (SNP) | VAF 311/416 reads (75%) | catalogued as rs200458194, COSV53943727, COSV99555687, COSV99555740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71626178 T>C | 5'Flank (SNP) | VAF 177/222 reads (80%) | called by muse, mutect2, varscan2
- NDRG4 | c.621-65T>G | Intron (SNP) | VAF 101/148 reads (68%) | called by muse, mutect2, varscan2
- PDZD4 | c.297-488C>T | Intron (SNP) | VAF 152/368 reads (41%) | catalogued as rs1416608914; called by muse, varscan2
- PLSCR1 | c.-13-14A>G | Intron (SNP) | VAF 180/439 reads (41%) | called by muse, mutect2, varscan2
- SCN11A | c.*14C>T | 3'UTR (SNP) | VAF 132/156 reads (85%) | catalogued as rs775582905; called by muse, mutect2, varscan2
- ST8SIA1 | c.-64G>A | 5'UTR (SNP) | VAF 38/96 reads (40%) | catalogued as rs987457420; called by muse, mutect2, varscan2
- TGIF1 | c.-234T>C | 5'UTR (SNP) | VAF 133/452 reads (29%) | called by muse, mutect2, varscan2
- TSPAN12 | c.*89A>C | 3'UTR (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
